Gene-level copy-number profile of tumor specimen TCGA-AA-3979-01A from TCGA case TCGA-AA-3979, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.2 years (30,742 days).
Specimen TCGA-AA-3979-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.0e4bbf49-e936-47d5-8543-1ed9f21778f7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3979-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f81f32d6-8e11-4493-bf5c-bbe9878f57ca

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 13,077; copy number 2: 40,713; copy number 3: 4,482; copy number 4: 6; copy number 5: 1,521; copy number 6: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3979-01A-01D-1018-01): tumor purity 0.92, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,532 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–71,702,786, 382 genes, copy number 5 (broad region; genes not listed).
- chr8:71,828,167–145,066,685, 1,150 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,697. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
